Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3887, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3887-01A (Primary Tumor).

Structured findings:

The material in I) is an advanced carcinoma, namely a mucinous adenocarcinoma of the colon with penetration of all parietal layers and vascular infiltrates (G3, pT3, L1, V1), with regard to the resection margins of the mucosa they show a regular mucosa, submucosa and muscularis, with regard to the radial resection margin they show a free resection margin with mature fatty connective tissue and related vascular portions, with regard to the lymph nodes they show free lymph nodes (0/14)

Source: NCI Genomic Data Commons file ef626d3c-ea29-43fe-8265-d1f1f5073f97 (TCGA-AG-3887.2E39B422-BCA0-4176-899F-1D55F656902E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).